TCGA case TCGA-WE-A8K5 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Norfolk and Norwich Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f579238-5a11-4adc-9c80-572cbb2ce58f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 65 years; Vital status: Dead; Days to death: 1,860 days (5.1 years).

Diagnoses (5)
1. Lentigo maligna melanoma (the primary disease): ICD-O-3 morphology code: 8742/3; ICD-10 code: C49.20; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: Progression; Age at diagnosis: 69.3 years (25,294 days); Days to diagnosis: 1,457 days (4.0 years); Prior treatment: No; Days to last follow up: 1,860 days (5.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,837 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N3; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,609 days (4.4 years); Days to treatment end: 1,623 days (4.4 years); Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ipilimumab; Days to treatment start: 1,823 days (5.0 years); Days to treatment end: 1,860 days (5.1 years); Treatment outcome: Progressive Disease.
4. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 65.4 years (23,886 days); Days to diagnosis: 49 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 29 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
5. Metastasis of diagnosis 3 (Lentigo maligna melanoma), site: Brain, NOS. Age at diagnosis: 69.4 years (25,335 days); Days to diagnosis: 1,498 days (4.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (3 entries)
- Day 1,498 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 1,498 days (4.1 years).
- Days to follow up: 1,654 days (4.5 years); Disease response: With Tumor.
- Days to follow up: 1,860 days (5.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 12.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WE-A8K5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-WE-A8K5-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WE-A8K5-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WE-A8K5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.7; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ankle; Other malignancy histological type: superficial basal cell carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: excision.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,860 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,860 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,498 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WE-A8K5-06A-11D-A371-01): tumor purity 0.72, ploidy 3.98, whole-genome doublings 1.
